Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A6V1, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A6V1-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

FINAL

Report Type Pathology Report
Date of Event
Sex
Authored by
Hosp/Group
Record Status FINAL

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3
Site ④ Tonsil NOS
C09.9
JW 8/2/13

FINAL DIAGNOSIS:

PART 1: LEFT TONSIL, TONSILLECTOMY

- A. INVASIVE SQUAMOUS CELL CARCINOMA, 2.1 CM, NON-KERATINIZING.
- B. PERINEURAL INVASION IS ABSENT.
- C. CARCINOMA EXTENDS TO THE SUPERIOR TISSUE EDGE AND IS < 0.1 CM FROM THE DEEP TISSUE EDGE.
- D. IMMUNOHISTOCHEMICAL STAIN FOR P16 IS POSITIVE (AS A SURROGATE MARKER FOR HUMAN PAPILLOMAVIRUS).
- E. pT2.

PART 2: LEFT POSTERIOR PHARYNGEAL WALL, BIOPSY
NO TUMOR SEEN.

PART 3: LEFT DEEP CONSTRUCTOR, BIOPSY
NO TUMOR SEEN.

PART 4: SOFT PALATE, BIOPSY
NO TUMOR SEEN.

PART 5: RIGHT TONSIL, TONSILLECTOMY

- A. INVASIVE SQUAMOUS CELL CARCINOMA, ABOUT 0.8 CM, NON-KERATINIZING.
- B. MARGINS ARE FREE OF CARCINOMA.

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received unfixed in five parts.

Part 1 is labeled with the patient's name, initials XX and "left tonsil, short

stitch superior, long stitch posterior". The specimen consists of a 3.0 x 2.2

x 1.5 cm tonsillectomy. There is a long suture designating the posterior and

a short suture designating superior.

There is a tan-gray, soft and firm lesion present measuring 2.1 x 1.2 x 1.0

cm. The lesion comes to within 0.2 cm of the posterior margin. The lesion is

0.3 cm from superior, 0.4 cm from anterior, 0.2 cm from the deep and 0.2 cm

[page 2 of 4]
from anterior.

Remainder of the specimen consists of tan-gray, soft focally hemorrhagic

amount of mucosa and tan-brown, focally hemorrhagic muscle. Following frozen

section consult digital images are taken. Banked for

Ink code:

Blue- superior

Green- posterior

Black- deep

Orange - inferior

Red- anterior and Area banked

Section code:

1AFS - remainder of the tissue is frozen is submitted

1B - shave of the superior margin

1C - shave of the inferior margin

1D-1G - remainder of specimen entirely submitted

Formalin exposure time: 30 hours

Part 2 is labeled with the patient's name, initials XX and "left posterior

pharyngeal wall". It the specimen consists of a 1.2 x 0.5 x 0.3 cm tan-gray,

soft to firm strip of mucosa and roughened tissue. The specimen is entirely

submitted in cassette labeled 2A.

Formalin exposure time: 28 hours

Part 3 is labeled with the patient's name, initials XX and "left deep constrictor". The specimen consists of a tan-brown, soft to firm, roughened

and cauterized un-oriented fragment of tissue measuring 2.0 x 0.6 x 0.3 cm.

The specimen is entirely submitted in cassette labeled 3A.

Formalin exposure time: 28 hours

Part 4 is labeled with the patient's name, initials XX and "soft palate". The

specimen consists of a tan-pink, soft to firm and cauterized portion of tissue

measuring 0.6 x 0.3 x 0.2 cm. The specimen is entirely submitted cassette

labeled 4A.

Formalin exposure time: 28 hours

Part 5 is labeled with the patient's name, initials XX and "right tonsil".

The specimen consists of a 3.0 x 2.0 x 1.0 cm tan-pink, soft, focally hemorrhagic, cauterized and un-oriented portion of tissue grossly resembling a

tonsil. The area of cautery is inked and the specimen is serially cross

sectioned. Upon cross section reveals multiple crypts with yellow mucoid

material present. The specimen is entirely submitted on cut surface in cassettes labeled 5A through 5C.

Formalin exposure time: 28 hours

GROSSED BY:

INTRAOPERATIVE CONSULTATION:

[page 3 of 4]
1 AFS: TONSIL, LEFT, ANTERIOR, POSTERIOR, DEEP MARGINS, RADIAL,
TONSILLECTOMY
(frozen section)-

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. MALIGNANT.
- C. NON-KERATINIZING SQUAMOUS CELL CARCINOMA.
- D. MARGINS WERE SUBMITTED SEPARATELY
- E. DISCUSSED WITH -

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

Part 5: Immunohistochemical stain for p16 (positive) was repeated on
Part 5

(in addition to Part 1) to better appreciate the extent of second focus
of
squamous cell carcinoma (contralateral focus).

The following statement applies to all immunohistochemistry, Insitu
Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and
Immunofluorescent Testing:

The testing was developed and its performance characteristics
determined by

the as required by
the CLIA

'88 regulations. The testing has not been cleared or approved for the
specific use by the U.S. Food and Drug Administration, but the FDA has
determined such approval is not necessary for clinical use. Tissue
fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement
Amendments of 1988 ("CLIA") as qualified to perform high-complexity
clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this
laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY
GLAND

TUMORS

SPECIMEN TYPE: Resection: tonsillectomy

TUMOR SITE: Pharynx, oropharynx

TUMOR SIZE: Greatest dimension: 2.1 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: Not applicable

PRIMARY TUMOR (pT): pT2

REGIONAL LYMPH NODES (pN): pNX

DISTANT METASTASIS (pM): pMX

MARGINS: Cannot be assessed

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Indeterminate

PERINEURAL INVASION: Absent

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Tonsil cancer

[page 4 of 4]
PROCEDURE: Tonsillectomy
SPECIFIC CLINICAL QUESTION: Not answered
OUTSIDE TISSUE DIAGNOSIS: Not answered
PRIOR MALIGNANCY: Not answered
CHEMOTHERAPY: Not answered
ORGAN TRANSPLANT: Not answered
IMMUNOSUPPRESSION: Not answered
OTHER DISEASES: Not answered
HISTO TISSUE SUMMARY/SLIDES REVIEWED:
Part 1: Tonsil, Left

Taken: Received:

Stain/ Block

H&E x 1 B
H&E x 1 C
ANEG Mouse x 1 D
H&E x 1 D
P16 x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 AFS

IMSU x 1 (none)

Part 2: Left Pharyngeal Wall

Taken: Received:

Stain/ Block

H&E x 1 A

Part 3: Left Deep Constriction

Taken: Received:

Stain/ Block

H&E x 1 A

Part 4: Soft Palate Biopsy

Taken: Received:

Stain/ Block

H&E x 1 A

H&E x 1 A

Part 5: Tonsil, Right

Taken: Received:

Stain/cn Block

ANEG Mouse x 1 A

H&E x 1 A

P16 x 1 A

H&E x 1 B

H&E x 1 C

CONSULTING PATHOLOGIST(S):

TC1

IIA Discrepancy		✓

Source: NCI Genomic Data Commons file be12d9f8-ad29-486e-ae48-317561578ca6 (TCGA-CN-A6V1.D671DB14-574E-468B-8296-3B5CA4B33B01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).